Gene-level copy-number profile of tumor specimen HTMCP-03-06-02266-01A from CGCI case HTMCP-03-06-02266, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02266-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f6f0748-57b4-4226-80f9-f3e6a8f075bf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02266-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,258 have no estimate.
https://portal.gdc.cancer.gov/files/5ec574de-7c41-4cd7-a880-0cf38dbe851a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,085; copy number 2: 16,500; copy number 3: 21,934; copy number 4: 9,222; copy number 5: 7,641; copy number 6: 460; copy number 7: 104; copy number 8: 352; copy number 9: 3; copy number 10: 7; copy number 11: 47; copy number 12: 8.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,838,125–12,841,357, 1 gene: PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–3): PRAMEF2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 521 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,975,087–146,036,746, 67 genes, copy number 7 (broad region; genes not listed).
- chr1:153,259,687–153,396,771, 9 genes, copy number 7: LORICRIN, PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A.
- chr1:196,774,813–196,795,407, 1 gene, copy number 9: CFHR3.
- chr1:208,022,242–208,244,384, 2 genes, copy number 7: PLXNA2, AL590138.1.
- chr2:89,252,211–89,310,144, 8 genes, copy number 12: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr5:43,486,709–43,515,148, 1 gene, copy number 7 (within-gene range 6–7): C5orf34.
- chr5:43,511,058–45,895,970, 24 genes, copy number 7: C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:38,269,491–38,311,808, 7 genes, copy number 10 (within-gene range 5–10): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,086,407–22,497,718, 57 genes, copy number 8–11: TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.
- chr15:87,325,829–101,903,204, 341 genes, copy number 8 (broad region; genes not listed).
- chr16:33,976,039–33,991,551, 2 genes, copy number 9 (within-gene range 3–9): AC133561.1, BCAP31P1.
- chr18:14,903,580–14,915,628, 1 gene, copy number 7: AP005121.1.

Autosomal genes at a single copy (total copy number 1): 2,085. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
